Somatic mutation profile of tumor specimen TCGA-HC-7818-01A (aliquot TCGA-HC-7818-01A-11D-2114-08) from TCGA case TCGA-HC-7818, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,391 days).
Specimen TCGA-HC-7818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a16f16ed-98fc-4481-b6c0-3a450c220fb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7818-10A (Blood Derived Normal), aliquot TCGA-HC-7818-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95e0fe6f-9710-4493-8d84-0176a5f6d194

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD16 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV65212785, COSV65213126; called by muse, mutect2
- CHCHD2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV68169875; called by muse, mutect2
- DAXX | c.1819A>G p.M607V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1290385226, COSV56467436; called by muse, mutect2
- DRC1 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV56529700; called by muse, mutect2, varscan2
- GINM1 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV66389520, COSV66389944; called by muse, mutect2
- KLHL42 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV67145701, COSV67145752; called by muse, mutect2
- KRTAP3-1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.288); catalogued as rs141325742; called by muse, mutect2
- MGAT4C | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.69); catalogued as rs748796788, COSV59829726; called by muse, mutect2
- MYBPC2 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as rs371496229; called by muse, mutect2, varscan2
- NRCAM | c.3145G>T p.D1049Y (on ENST00000379028 / NM_001371124.1; = p.D1033Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV61032657; called by muse, mutect2
- PRMT3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV58175223; called by muse, mutect2, varscan2
- SETD2 | c.2672A>T p.K891M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV57432558; called by muse, mutect2, varscan2
- GAD2 | c.1023C>T p.Y341= | Silent (SNP) | VAF 20/211 reads (9%) | catalogued as rs778735807, COSV52149809; called by muse, mutect2
- PADI1 | c.243C>A p.G81= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV64937902; called by muse, mutect2
- SLIT1 | c.1665G>A p.L555= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV56584610; called by muse, mutect2
